Gene-level copy-number profile of tumor specimen TCGA-IN-A6RI-01A from TCGA case TCGA-IN-A6RI, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.0 years (16,788 days).
Specimen TCGA-IN-A6RI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.de54a346-60cc-40c7-9f51-6105ecfda833.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IN-A6RI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 845 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9fa94cc6-a5cd-4774-bfc3-c0e71aa1b6e3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 17,912; copy number 2: 40,061; copy number 3: 1,143; copy number 4: 377; copy number 5: 60; copy number 6: 20; copy number 7: 8; copy number 8: 7; copy number 9: 29; copy number 10: 63; copy number 11: 49; copy number 14: 18; copy number 16: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IN-A6RI-01A-11D-A32M-01): tumor purity 0.7, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,021,249–60,033,020, 1 gene: AC034234.1.
- chr10:122,374,696–122,461,383, 3 genes (within-gene range 0–1): PLEKHA1, MIR3941, BX842242.1.
- chr11:1,012,823–1,110,511, 3 genes: MUC6, LINC02688, MUC2.
- chr16:78,525,189–78,796,362, 4 genes: AC046158.4, AC046158.2, AC046158.3, AC009141.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 274 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:118,766,965–119,662,251, 14 genes, copy number 6: LINC01956, EN1, MARCO, AC013457.1, C1QL2, RN7SL468P, STEAP3, STEAP3-AS1, C2orf76, DBI, TMEM37, SCTR, SCTR-AS1, CFAP221.
- chr11:22,622,533–26,047,598, 26 genes, copy number 5–9: FANCF, GAS2, RNA5SP338, SVIP, AC006299.1, CCDC179, LINC02718, AC100767.2, WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1, LINC02726, AC100768.1, RNU6-783P, AC099842.1, LINC02686, LUZP2, AC115990.1, AC087373.1, RPL36AP40, AC100770.1, LINC02699, AC013799.1, AC024341.1.
- chr11:28,108,248–31,509,645, 36 genes, copy number 5–8: METTL15, ATP5MGP8, RN7SKP158, AC104978.1, MIR8068, AC013714.1, LINC02758, LINC02742, OR2BH1P, AC090791.1, AC110056.1, LINC02755, AC090124.2, AC090124.1, AC110058.1, LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58, LINC01616, KCNA4, AL358944.1, AL358944.2, FSHB, ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1, DCDC1, CYCSP25, AL137804.1, DNAJC24, IMMP1L.
- chr19:10,598,001–10,713,437, 5 genes, copy number 6: AC011475.1, SLC44A2, ILF3-DT, ILF3, QTRT1.
- chr19:10,718,404–10,718,503, 1 gene, copy number 6: MIR638.
- chr19:12,995,475–13,633,025, 15 genes, copy number 9 (within-gene range 3–9): NFIX, AC138474.1, AC007787.1, AC007787.2, LYL1, TRMT1, NACC1, AC005546.1, AC011446.1, STX10, IER2, AC011446.3, AC011446.2, RPL12P42, CACNA1A.
- chr19:13,772,118–13,961,449, 16 genes, copy number 5: AC008686.1, C19orf53, ZSWIM4, AC020916.2, RN7SL619P, AC020916.1, MIR24-2, MIR27A, MIR23A, NANOS3, MIR181C, MIR181D, C19orf57, CC2D1A, PODNL1, DCAF15.
- chr19:28,960,506–30,085,893, 31 genes, copy number 9–16: AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.
- chr20:52,972,358–59,847,711, 130 genes, copy number 10–14 (within-gene range 1–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,533. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
